Somatic mutation profile of tumor specimen TCGA-W5-AA30-01A (aliquot TCGA-W5-AA30-01A-31D-A417-09) from TCGA case TCGA-W5-AA30, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 82.2 years (30,039 days).
Specimen TCGA-W5-AA30-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4cdc419a-8f7e-498b-9068-6413f3ab5f99.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W5-AA30-10A (Blood Derived Normal), aliquot TCGA-W5-AA30-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2f3da50-ab79-4ee8-a389-0cd2210a276c

The open-access MAF lists 58 somatic variants for this specimen: 44 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 37, Silent 14, Frame Shift Del 2, Splice Site 2, In Frame Del 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACBD3 | c.664_687del p.L222_R229del | In Frame Del (DEL) | VAF 8/54 reads (15%) | catalogued as rs767031016; called by mutect2, varscan2
- BRCA2 | c.4540G>C p.E1514Q | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.255); catalogued as COSV66455611; called by muse, mutect2, varscan2
- CTNNA2 | c.2116G>C p.D706H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100559678, COSV58136648, COSV58140250; called by muse, mutect2, varscan2
- DAPK1 | c.507C>G p.D169E | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs369801129; called by muse, mutect2, varscan2
- FERMT1 | c.386-1G>A p.X129_splice | Splice Site (SNP) | VAF 4/42 reads (10%) | catalogued as COSV54097942; called by muse, mutect2
- FPR1 | c.570G>T p.R190S | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.219); catalogued as COSV59053986; called by muse, mutect2, varscan2
- GATAD2A | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.383); catalogued as rs527342598; called by muse, mutect2, varscan2
- KIF19 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776836395, CM156724, COSV63429222; called by muse, mutect2
- LRRC52 | c.460T>C p.Y154H | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as rs1422965626; called by muse, mutect2
- PBRM1 | c.1762G>T p.E588* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV56296192, COSV99970661; called by mutect2, varscan2
- PDCD2L | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372339509; called by muse, mutect2, varscan2
- TM9SF3 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs950884960; called by muse, mutect2, varscan2
- ZNF431 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV60671828; called by muse, mutect2, varscan2
- ANGEL1 | c.794A>G p.Y265C | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK2 | c.10729G>A p.A3577T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- APOB | c.12761del p.P4254Lfs*4 | Frame Shift Del (DEL) | VAF 12/55 reads (22%) | called by mutect2, pindel, varscan2
- B4GALNT3 | c.2275A>G p.N759D | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CAPRIN1 | c.694G>C p.V232L | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.009); called by muse, mutect2
- CHAMP1 | c.423G>C p.L141F | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- CLHC1 | c.464G>C p.C155S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSE1L | c.476G>A p.R159K | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- DCHS1 | c.6716T>A p.I2239N | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DHX9 | c.2185A>G p.I729V | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- ELF3 | c.1058A>C p.K353T | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EML5 | c.3716C>T p.T1239I | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- ISY1-RAB43 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- JMJD4 | c.490T>C p.Y164H | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- KCNT2 | c.2212C>T p.P738S | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- KIAA1109 | c.9387T>C p.S3129= | Splice Region (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- KIF4B | c.2837A>C p.K946T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LAMA3 | c.9293C>T p.S3098F (on ENST00000313654 / NM_198129.4; = p.S1489F on NM_000227.6) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.041); called by muse, mutect2
- PCDH7 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- PLA2G4E | c.2407G>A p.E803K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PPP1CB | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PRPF8 | c.1895C>T p.A632V | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2
- PSPC1 | c.1451G>A p.G484D | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); called by muse, mutect2
- PTCD2 | c.531C>G p.I177M | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.055); called by muse, mutect2
- PVR | c.1115G>T p.R372L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- RUFY1 | c.891-4_891del p.X297_splice | Splice Site (DEL) | VAF 11/102 reads (11%) | called by mutect2, pindel, varscan2
- ST6GALNAC3 | c.13C>G p.L5V | Missense Mutation (SNP) | VAF 6/39 reads (15%) | PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- SYT12 | c.83_120del p.A28Efs*61 | Frame Shift Del (DEL) | VAF 6/74 reads (8%) | called by mutect2, pindel
- ZNF100 | c.1075A>G p.T359A | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ZNF14 | c.1571T>A p.I524N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- ZNF534 | c.521A>T p.N174I (on ENST00000332323 / NM_001143939.3; = p.N161I on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- AMMECR1L | c.591C>A p.L197= | Silent (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- CACNA1F | c.5598C>T p.G1866= | Silent (SNP) | VAF 13/22 reads (59%) | called by muse, mutect2, varscan2
- CELF4 | c.903C>T p.A301= | Silent (SNP) | VAF 14/43 reads (33%) | called by muse, mutect2, varscan2
- CRACDL | c.2835A>G p.E945= | Silent (SNP) | VAF 8/37 reads (22%) | called by muse, mutect2, varscan2
- KCNMB2 | c.588G>A p.L196= | Silent (SNP) | VAF 17/43 reads (40%) | called by muse, mutect2, varscan2
- NLRP11 | c.162C>T p.N54= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs144479075; called by muse, mutect2, varscan2
- NSD1 | c.7311A>G p.K2437= | Silent (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- RPS6KA3 | c.1866T>C p.P622= | Silent (SNP) | VAF 4/70 reads (6%) | called by muse, mutect2
- RTL3 | c.1149T>C p.S383= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs1272417570; called by muse, mutect2, varscan2
- SORBS1 | c.2418T>G p.A806= (on ENST00000361941 / NM_001034954.2; = p.A456= on NM_006434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/38 reads (34%) | called by muse, mutect2, varscan2
- SPTBN2 | c.4081C>T p.L1361= | Silent (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2, varscan2
- TACC3 | c.510T>C p.S170= | Silent (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2, varscan2
- TECPR1 | c.2793C>G p.P931= | Silent (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- TLR3 | c.1644C>T p.H548= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs147873871; called by muse, mutect2, varscan2
